Somatic mutation profile of tumor specimen MMRF_2114_1_BM_CD138pos (aliquot MMRF_2114_1_BM_CD138pos_T1_KHS5U_L08682) from MMRF case MMRF_2114, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.6 years (19,573 days).
Specimen MMRF_2114_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e7fb516-6bf0-4c72-bac0-3ead6afaa1c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2114_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2114_1_PB_Whole_C2_KHS5U_L08683; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc69abc9-cede-4d98-9f6b-0dce6849be50

The open-access MAF lists 84 somatic variants for this specimen: 30 protein-altering or splice-affecting, 15 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 22, Silent 15, Intron 7, 5'UTR 6, RNA 2, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 20/202 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CELF4 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV58464520; called by muse, mutect2
- DLGAP2 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs762050332, COSV70098404; called by muse, mutect2, varscan2
- FGD5 | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1186736840; called by muse, mutect2, varscan2
- FOXN2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 156/311 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as rs1273031003, COSV61320362; called by muse, mutect2, varscan2
- GABRA1 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV50117498; called by muse, mutect2, varscan2
- GBP4 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs780118405, COSV104418764; called by muse, mutect2, varscan2
- HNF1A | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.291); catalogued as COSV57460428; called by muse, mutect2, varscan2
- IRF6 | c.827T>A p.F276Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104424048; called by muse, mutect2, varscan2
- MFSD6L | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199909477; called by muse, mutect2, varscan2
- OR4S2 | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56746880; called by muse, mutect2
- PDGFRA | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV57268267; called by muse, mutect2, varscan2
- QRFPR | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs751553958, COSV57677217; called by muse, mutect2, varscan2
- SOX8 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs769539375, COSV53508667, COSV53510251, COSV53510554; called by muse, varscan2
- ACP7 | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DLGAP2 | c.1583T>G p.V528G | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- DNAH12 | c.9146G>C p.S3049T (on ENST00000351747; = p.S3917T on NM_001366028.2) | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- EVI2B | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- HBS1L | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- HP | c.386dup p.N129Kfs*2 | Frame Shift Ins (INS) | VAF 78/110 reads (71%) | called by mutect2, pindel, varscan2
- KCNA4 | c.1693T>A p.Y565N | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.306); called by muse, mutect2
- MADD | c.2579G>A p.S860N | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NPAP1 | c.1379A>C p.N460T | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.096); called by muse, mutect2
- PARD3B | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PIWIL4 | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REN | c.829G>T p.G277W | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLCO1A2 | c.1468T>C p.S490P | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF189 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF462 | c.1403C>G p.A468G | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- ABCB9 | c.1470G>T p.V490= (on ENST00000280560 / NM_019625.4; = p.V447= on NM_019624.3) | Silent (SNP) | VAF 23/264 reads (9%) | called by muse, mutect2
- ACSS1 | c.657C>T p.F219= | Silent (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- CAMK2D | c.624T>G p.L208= | Silent (SNP) | VAF 79/141 reads (56%) | called by muse, mutect2, varscan2
- EPX | c.930C>T p.D310= | Silent (SNP) | VAF 110/233 reads (47%) | catalogued as rs150544366; called by muse, varscan2
- MTRR | c.45C>T p.V15= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs372674593; called by muse, mutect2, varscan2
- NRK | c.840C>T p.S280= | Silent (SNP) | VAF 22/347 reads (6%) | catalogued as rs753383727; called by muse, mutect2
- NUBP2 | c.366C>T p.A122= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- OR8K1 | c.477G>A p.T159= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as rs1423449297, COSV54403454; called by muse, varscan2
- OTOG | c.1092C>T p.Y364= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs780285643; called by muse, mutect2, varscan2
- SALL3 | c.1929C>T p.F643= | Silent (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- SLC52A3 | c.894G>A p.A298= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as rs532778217, COSV54078068; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRPM3 | c.3144C>T p.I1048= (on ENST00000357533 / NM_001366142.2; = p.I891= on NM_020952.6) | Silent (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- UPP1 | c.387C>T p.A129= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1203852956; called by muse, mutect2, varscan2
- WDR47 | c.1041C>T p.N347= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- YY1AP1 | c.1452T>C p.H484= (on ENST00000295566 / NM_139118.2; = p.H427= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- ACTBL2 | c.*1209G>A | 3'UTR (SNP) | VAF 42/92 reads (46%) | catalogued as rs1296659809; called by muse, mutect2, varscan2
- ARL8B | c.*421A>G | 3'UTR (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2
- BAG4 | c.*2491A>G | 3'UTR (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- CAPS2 | c.-80C>T | 5'UTR (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- CARHSP1 | c.*88C>T | 3'UTR (SNP) | VAF 14/31 reads (45%) | catalogued as rs1050914667; called by muse, mutect2, varscan2
- CDH2 | c.*311C>T | 3'UTR (SNP) | VAF 41/83 reads (49%) | catalogued as rs17493056; called by muse, mutect2, varscan2
- CDH2 | c.173-31633A>T | Intron (SNP) | VAF 49/193 reads (25%) | called by muse, mutect2, varscan2
- CREB1 | c.*562G>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | catalogued as rs779517246; called by muse, mutect2, varscan2
- DHRS3 | c.*13G>A | 3'UTR (SNP) | VAF 12/144 reads (8%) | catalogued as rs1375482622; called by muse, mutect2
- ENPEP | c.*899G>T | 3'UTR (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- ERBB4 | c.*2955G>A | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- FGFBP3 | c.*641C>T | 3'UTR (SNP) | VAF 8/21 reads (38%) | catalogued as rs1191338404; called by muse, mutect2, varscan2
- GABRA6 | c.-37C>A | 5'UTR (SNP) | VAF 28/261 reads (11%) | called by muse, mutect2
- HSPA13 | c.*2181A>G | 3'UTR (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- KDM4E | c.*293G>A | 3'UTR (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- KLF9 | c.*2570G>A | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44572144 A>T | 3'Flank (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- MMUT | c.*1335G>A | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- MRPS15 | c.-93C>A | 5'UTR (SNP) | VAF 93/96 reads (97%) | called by muse, mutect2, varscan2
- NAV3 | c.*630T>A | 3'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- NEXMIF | c.*1490T>G | 3'UTR (SNP) | VAF 31/51 reads (61%) | called by muse, mutect2, varscan2
- NPM1 | c.139-87G>A | Intron (SNP) | VAF 97/186 reads (52%) | called by muse, mutect2, varscan2
- NRG1 | c.503-6049T>C | Intron (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- OGDH | c.1206+216G>A | Intron (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- OR4C49P | n.335T>C | RNA (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- PRR16 | c.-39C>T | 5'UTR (SNP) | VAF 6/19 reads (32%) | catalogued as rs771315409; called by muse, mutect2, varscan2
- PRUNE2 | c.756+35231G>A | Intron (SNP) | VAF 19/217 reads (9%) | catalogued as COSV100943392; called by muse, mutect2
- RBCK1 | c.-303G>T | 5'UTR (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- RIN2 | c.*1235T>G | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- RPP40 | c.269-477C>T | Intron (SNP) | VAF 14/126 reads (11%) | catalogued as rs912836459; called by muse, mutect2
- SHE | c.*4182A>G | 3'UTR (SNP) | VAF 36/72 reads (50%) | catalogued as rs1406407906; called by muse, mutect2, varscan2
- SHROOM2 | c.*75C>A | 3'UTR (SNP) | VAF 35/173 reads (20%) | called by muse, mutect2, varscan2
- STIMATE | c.*1528G>A | 3'UTR (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- TMEM245 | c.*5146A>T | 3'UTR (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- TSPAN3 | c.*3617G>A | 3'UTR (SNP) | VAF 75/155 reads (48%) | called by muse, mutect2, varscan2
- U82695.1 | n.882C>A | RNA (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- UBE2A | c.152-47A>G | Intron (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- VPS11 | c.-961G>T | 5'UTR (SNP) | VAF 43/124 reads (35%) | called by muse, mutect2, varscan2
- ZNF385C | chr17:42026815 C>T | 3'Flank (SNP) | VAF 61/141 reads (43%) | called by muse, mutect2, varscan2
